Somatic mutation profile of tumor specimen MMRF_2523_1_BM_CD138pos (aliquot MMRF_2523_1_BM_CD138pos_T1_KHS5U_L11638) from MMRF case MMRF_2523, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,458 days).
Specimen MMRF_2523_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 499bbbe6-ed5e-4a97-8392-e8a7cce2cb90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2523_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2523_1_PB_Whole_C3_KHS5U_K15185; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dffebbb5-7a5e-4d4d-a584-1cefcb1b31ea

The open-access MAF lists 114 somatic variants for this specimen: 48 protein-altering or splice-affecting, 18 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 23, Silent 18, Intron 12, 5'UTR 6, RNA 3, 5'Flank 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 60/262 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 13/122 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADGRG4 | c.8597C>T p.A2866V | Missense Mutation (SNP) | VAF 148/264 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV54953138; called by muse, mutect2, varscan2
- C15orf39 | c.2662G>T p.A888S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100641282; called by muse, mutect2, varscan2
- DCAF12L1 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV64421504; called by muse, mutect2, varscan2
- DLL1 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.129); catalogued as rs773530345, COSV64537094; called by muse, mutect2, varscan2
- DNAJC7 | c.238del p.E80Kfs*10 | Frame Shift Del (DEL) | VAF 56/149 reads (38%) | catalogued as rs1567963941; called by mutect2, pindel, varscan2
- FAM189A2 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554682942, COSV99975189; called by muse, mutect2, varscan2
- GNAQ | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV54125773; called by muse, mutect2, varscan2
- HLA-DRA | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs764172368, COSV66622675; called by muse, mutect2
- IGF1R | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV99151653; called by mutect2, varscan2
- IGLV7-46 | c.324C>G p.Y108* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as rs377179353; called by muse, mutect2, varscan2
- ITGB2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs148775158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR6V1 | c.238C>T p.L80F | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101389589; called by muse, mutect2, varscan2
- PRDM2 | c.4122A>T p.K1374N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99341188; called by muse, mutect2, varscan2
- SDK1 | c.5872G>A p.A1958T | Missense Mutation (SNP) | VAF 122/377 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.636); catalogued as rs144039473; called by muse, mutect2, varscan2
- SPG7 | c.1783G>A p.A595T (on ENST00000268704; = p.A602T on NM_003119.4) | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs754771891, COSV99244671; called by muse, mutect2, varscan2
- SRA1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 106/163 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs369799757; called by muse, mutect2, varscan2
- TMEM244 | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV63743370; called by muse, mutect2, varscan2
- ZNF471 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV57293483; called by muse, mutect2, varscan2
- ADGRG2 | c.874G>T p.V292F (on ENST00000379869 / NM_001079858.3; = p.V289F on NM_005756.4) | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- BRD2 | c.1959C>G p.D653E | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC47 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- CYLC2 | c.1002T>G p.N334K | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DHDH | c.983C>A p.T328N | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GJA8 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV4-60 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- IGLV5-45 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KIAA1109 | c.9059T>A p.F3020Y | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KIF19 | c.2002A>G p.T668A | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT26 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- NPR1 | c.2810A>C p.N937T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHA3 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- PIAS1 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 60/430 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCL1 | c.2997del p.X999_splice | Splice Site (DEL) | VAF 87/208 reads (42%) | called by mutect2, pindel, varscan2
- PQBP1 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTDSS1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- PTPN23 | c.921A>G p.G307= | Splice Region (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- PTPRD | c.2722G>T p.V908L | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PTPRD | c.2721G>T p.M907I | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCMH1 | c.196G>A p.A66T (on ENST00000326197 / NM_001031694.2; = p.A19T on NM_012236.4) | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SP140 | c.237+5G>A | Splice Region (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- SPTBN4 | c.7517del p.L2506Cfs*10 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | called by mutect2, varscan2
- SQSTM1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2
- SVEP1 | c.10711T>C p.F3571L | Missense Mutation (SNP) | VAF 120/371 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYCP2 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- VGLL3 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ZNF285 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2
- C10orf90 | c.462G>A p.L154= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- C2orf69 | c.975T>C p.I325= | Silent (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- CTNNA1 | c.210G>A p.E70= | Silent (SNP) | VAF 24/159 reads (15%) | catalogued as rs1369673536, COSV57073970, COSV57078506; called by muse, mutect2, varscan2
- DSG2 | c.456C>A p.I152= | Silent (SNP) | VAF 106/234 reads (45%) | called by muse, mutect2, varscan2
- GEMIN5 | c.1614A>G p.V538= | Silent (SNP) | VAF 53/158 reads (34%) | called by muse, mutect2, varscan2
- HOXA5 | c.117C>T p.S39= | Silent (SNP) | VAF 41/392 reads (10%) | catalogued as rs1260240228; called by muse, mutect2
- MAGEL2 | c.2646C>T p.S882= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as rs747679005, COSV58566556; called by muse, mutect2, varscan2
- MYBPC2 | c.492T>C p.S164= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as rs1455781734; called by muse, mutect2
- SIRPG | c.576C>T p.F192= | Silent (SNP) | VAF 75/153 reads (49%) | called by muse, mutect2, varscan2
- SMC6 | c.3207T>C p.D1069= | Silent (SNP) | VAF 140/303 reads (46%) | called by muse, mutect2, varscan2
- SPICE1 | c.573T>C p.D191= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- SRPK1 | c.1476G>A p.K492= | Silent (SNP) | VAF 27/312 reads (9%) | called by muse, mutect2
- SUSD2 | c.1431G>A p.A477= | Silent (SNP) | VAF 40/296 reads (14%) | catalogued as rs766871550; called by muse, mutect2, varscan2
- SYNE2 | c.8835C>T p.C2945= | Silent (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2
- TMEM151B | c.831C>T p.N277= | Silent (SNP) | VAF 149/459 reads (32%) | catalogued as rs1388629719; called by muse, mutect2, varscan2
- TUBA4A | c.1017C>T p.R339= | Silent (SNP) | VAF 74/160 reads (46%) | called by muse, mutect2, varscan2
- TXNDC5 | c.1005C>T p.T335= | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as COSV99306338; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1002A>G p.L334= | Silent (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- ACTG1 | c.-138T>C | 5'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- ASB5 | c.*1336C>G | 3'UTR (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021401 G>C | 5'Flank (SNP) | VAF 93/163 reads (57%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- BNIP2 | c.*4018T>C | 3'UTR (SNP) | VAF 38/107 reads (36%) | catalogued as rs1156681285; called by muse, mutect2, varscan2
- BNIP2 | c.*3922G>A | 3'UTR (SNP) | VAF 48/137 reads (35%) | catalogued as rs750421510; called by muse, mutect2, varscan2
- C5orf60 | chr5:179645026 C>T | 5'Flank (SNP) | VAF 56/215 reads (26%) | called by muse, mutect2, varscan2
- CDK19 | c.*2510A>T | 3'UTR (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- CHST13 | c.*204C>T | 3'UTR (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- CNTN2 | c.*1923C>A | 3'UTR (SNP) | VAF 37/71 reads (52%) | catalogued as rs1420866150; called by muse, mutect2, varscan2
- CYP17A1 | c.970-68C>A | Intron (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- GABRA4 | c.*1616C>A | 3'UTR (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- GABRQ | c.*22C>T | 3'UTR (SNP) | VAF 102/192 reads (53%) | catalogued as rs782235697, COSV64781663; called by muse, mutect2, varscan2
- GALNT17 | c.*1251C>T | 3'UTR (SNP) | VAF 21/271 reads (8%) | catalogued as rs948387082; called by muse, mutect2
- GIMAP1 | c.*1351C>T | 3'UTR (SNP) | VAF 90/250 reads (36%) | catalogued as rs981868502; called by muse, mutect2, varscan2
- GPAT2 | c.2150-17T>A | Intron (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- HIPK2 | c.*306del | 3'UTR (DEL) | VAF 28/100 reads (28%) | called by mutect2, pindel, varscan2
- HTR2A | c.*247A>T | 3'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- LHX8 | c.-292G>A | 5'UTR (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- LINC01164 | n.842del | RNA (DEL) | VAF 29/79 reads (37%) | catalogued as rs952020245; called by mutect2, pindel, varscan2
- LINC02291 | n.473C>G | RNA (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- LYN | c.*581T>G | 3'UTR (SNP) | VAF 57/112 reads (51%) | called by muse, mutect2, varscan2
- LZTS2 | c.-2366G>A | 5'UTR (SNP) | VAF 111/223 reads (50%) | called by muse, mutect2, varscan2
- MIR146A | n.73C>T | RNA (SNP) | VAF 19/54 reads (35%) | called by muse, mutect2, varscan2
- MPPED2 | c.*155T>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- NKAIN4 | c.472-424C>A | Intron (SNP) | VAF 5/84 reads (6%) | catalogued as rs927148940; called by muse, mutect2
- NTRK2 | c.1585+9463C>T | Intron (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- PRKAA2 | c.*4029A>T | 3'UTR (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- PTP4A3 | c.*514C>T | 3'UTR (SNP) | VAF 17/52 reads (33%) | catalogued as rs918303212; called by muse, mutect2
- RIT1 | c.238-104G>A | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- RRAS2 | c.108+16792C>T | Intron (SNP) | VAF 127/238 reads (53%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.*167G>A | 3'UTR (SNP) | VAF 14/192 reads (7%) | catalogued as rs886839983; called by muse, mutect2
- SLITRK2 | chrX:145829288 T>G | 3'Flank (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- SPATC1L | c.-560C>A | 5'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- ST13 | chr22:40857113 C>T | 5'Flank (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- STIM2 | c.*1505C>T | 3'UTR (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- SYNE1 | c.26153+1154T>A | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2
- SYNE1 | c.26153+1152T>G | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2
- TBC1D8B | c.1838-508G>A | Intron (SNP) | VAF 34/81 reads (42%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*1511T>A | 3'UTR (SNP) | VAF 30/76 reads (39%) | called by muse, mutect2, varscan2
- THAP10 | c.*11T>G | 3'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs900243836; called by muse, mutect2, varscan2
- THAP3 | c.438+83A>G | Intron (SNP) | VAF 12/27 reads (44%) | catalogued as rs1042824435; called by muse, mutect2, varscan2
- TMEM179B | c.498+89T>C | Intron (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
- TPD52L1 | c.-68G>T | 5'UTR (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- TRPM2 | c.*382G>A | 3'UTR (SNP) | VAF 227/354 reads (64%) | catalogued as rs554075206; called by muse, mutect2
- TSNAX | c.-77C>T | 5'UTR (SNP) | VAF 30/70 reads (43%) | catalogued as rs1052564066; called by muse, mutect2, varscan2
- TUBB6 | c.277+42T>G | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- UBASH3A | c.*86G>A | 3'UTR (SNP) | VAF 158/235 reads (67%) | catalogued as rs976258298; called by muse, mutect2, varscan2
- VWA1 | c.*2860G>A | 3'UTR (SNP) | VAF 55/111 reads (50%) | called by muse, mutect2, varscan2
